Somatic mutation profile of tumor specimen 0DJO5M from CCDI case PBBXGC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 3.6 years (1,310 days).
Specimen 0DJO5M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b405ea4c-95ee-494f-a7b2-5ebe9f18263f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJO4U (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc802354-8a3f-4c5f-b800-9c078e6e1f2a

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 1, Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRIM1 | c.1255G>C p.D419H | Missense Mutation (SNP) | VAF 17/342 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- OR10G8 | c.9C>T p.N3= | Silent (SNP) | VAF 114/358 reads (32%) | catalogued as rs1276314044, COSV70908448; called by muse, mutect2, varscan2
- DUSP7 | c.-78C>T | 5'UTR (SNP) | VAF 4/44 reads (9%) | catalogued as rs1240337773; called by muse, mutect2
